Somatic mutation profile of tumor specimen TCGA-FV-A496-01A (aliquot TCGA-FV-A496-01A-11D-A25V-10) from TCGA case TCGA-FV-A496, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 84.7 years (30,950 days).
Specimen TCGA-FV-A496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a29c706-c696-4f31-8e69-478c8c45dd39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A496-10A (Blood Derived Normal), aliquot TCGA-FV-A496-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee7779f1-2c05-43bf-81c0-3778107799c8

The open-access MAF lists 134 somatic variants for this specimen: 100 protein-altering or splice-affecting, 28 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 28, Frame Shift Del 5, Nonsense Mutation 4, In Frame Del 3, Splice Region 3, Splice Site 2, RNA 2, 5'UTR 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.910T>A p.F304I | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67018339; called by muse, mutect2, varscan2
- ACLY | c.2678G>A p.C893Y | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61252145; called by muse, mutect2, varscan2
- ADAL | c.778T>C p.C260R (on ENST00000562188 / NM_001324366.2; = p.C233R on NM_001159280.3) | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67501153; called by muse, mutect2, varscan2
- AJAP1 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753347923, COSV65452932; called by muse, mutect2, varscan2
- ANK2 | c.4972G>C p.V1658L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as COSV52179262; called by muse, mutect2, varscan2
- ARMH3 | c.1892C>T p.T631M | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199549255, COSV64234012; called by muse, mutect2, varscan2
- ASAP1 | c.2520C>A p.D840E | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.967); catalogued as COSV63052694; called by muse, mutect2, varscan2
- ASPN | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs371768627; called by muse, mutect2
- BEND4 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.036); catalogued as COSV72468974; called by muse, mutect2, varscan2
- CACNA1D | c.6233C>T p.P2078L (on ENST00000350061 / NM_001128840.3; = p.P2098L on NM_000720.4) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55459147; called by muse, mutect2
- CACNA1E | c.2281C>A p.P761T | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV62410322; called by muse, mutect2, varscan2
- CDH8 | c.2184G>C p.R728S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54888076; called by muse, mutect2, varscan2
- CFAP206 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51536067; called by muse, mutect2, varscan2
- CFAP65 | c.4457C>T p.S1486F | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV58564747; called by muse, mutect2, varscan2
- CFL2 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53312181; called by muse, mutect2, varscan2
- COG7 | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1237019918, COSV56152138; called by muse, mutect2, varscan2
- CSMD3 | c.4784C>A p.S1595Y (on ENST00000297405 / NM_001363185.1; = p.S1491Y on NM_052900.3) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52253830, COSV52270600; called by muse, mutect2, varscan2
- CTNND1 | c.2491G>T p.G831* (on ENST00000399050 / NM_001085458.2; = p.G825* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV62385262, COSV62385841; called by muse, mutect2, varscan2
- CTNND1 | c.2492G>T p.G831V (on ENST00000399050 / NM_001085458.2; = p.G825V on NM_001331.3) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV104420723, COSV62382697; called by muse, mutect2, varscan2
- CYP2A7 | c.163T>A p.C55S | Missense Mutation (SNP) | VAF 120/263 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52504511; called by muse, mutect2, varscan2
- DEFB110 | c.31C>A p.H11N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64484753; called by muse, mutect2, varscan2
- DIMT1 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV52234420; called by muse, mutect2, varscan2
- DYNC2H1 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1302921684, COSV62102455; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2174C>A p.A725D | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100668716, COSV62569857; called by muse, mutect2
- EIF2B2 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CD067166, COSV56721147; called by muse, mutect2, varscan2
- FBLN1 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs775398109, COSV53052061; called by muse, mutect2, varscan2
- FBN2 | c.2111G>T p.S704I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV52534875; called by muse, mutect2, varscan2
- FCRL1 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as rs200955967, COSV63824536, COSV63826643; called by muse, mutect2, varscan2
- FLII | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1567712265, COSV58947012; called by muse, mutect2, varscan2
- FRAS1 | c.7852G>A p.V2618I | Missense Mutation (SNP) | VAF 101/191 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53633900; called by muse, mutect2, varscan2
- GCN1 | c.1667G>T p.R556I | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV56112820; called by muse, mutect2
- GPRIN3 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100310922, COSV60885017, COSV60886005; called by muse, mutect2, varscan2
- HDAC9 | c.1873C>A p.R625S | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV67766018, COSV67781511; called by muse, mutect2
- INCENP | c.1684G>A p.D562N (on ENST00000394818 / NM_001040694.2; = p.D558N on NM_020238.3) | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1302950403, COSV53919348, COSV53920621; called by muse, mutect2, varscan2
- ITGA5 | c.1463+3A>G | Splice Region (SNP) | VAF 24/107 reads (22%) | catalogued as COSV99516839; called by muse, mutect2, varscan2
- JAM3 | c.264G>C p.L88F | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV54455551; called by mutect2, varscan2
- KLHDC3 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV55063935, COSV55065381; called by muse, mutect2, varscan2
- KLHL33 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs781672639, COSV60727204; called by muse, mutect2, varscan2
- LGALS12 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.184); catalogued as COSV55371586; called by muse, mutect2, varscan2
- LRP1B | c.10857T>G p.C3619W | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV67257006; called by muse, mutect2, varscan2
- LRP8 | c.1775-1G>A p.X592_splice | Splice Site (SNP) | VAF 40/143 reads (28%) | catalogued as COSV60100490; called by muse, mutect2, varscan2
- LRRTM3 | c.577A>T p.I193F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100791822; called by muse, mutect2
- LUC7L3 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs753362684, COSV53588614; called by muse, mutect2, varscan2
- MAGEE2 | c.1466G>A p.R489K | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV64898270; called by muse, varscan2
- MCM7 | c.1708C>T p.Q570* | Nonsense Mutation (SNP) | VAF 4/59 reads (7%) | catalogued as COSV100385088; called by muse, mutect2
- MGAM | c.1748A>C p.H583P | Missense Mutation (SNP) | VAF 118/138 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72075297; called by muse, varscan2
- MYCBPAP | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs774395843, COSV60410393; called by muse, mutect2, varscan2
- MYOCD | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV58509066; called by muse, mutect2, varscan2
- NEB | c.11560G>C p.D3854H | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50881854, COSV51436297; called by muse, mutect2, varscan2
- NFKBIZ | c.618T>G p.N206K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV58201482; called by muse, mutect2, varscan2
- NUP160 | c.4165A>G p.I1389V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as rs62000434, COSV65855424; called by muse, mutect2, varscan2
- PAPOLB | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV68202805; called by muse, mutect2, varscan2
- PDPR | c.785C>G p.A262G | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.139); catalogued as COSV55354992; called by muse, mutect2, varscan2
- PEX6 | c.2927A>C p.K976T | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV55104668; called by muse, mutect2, varscan2
- POLR2A | c.5481_5501del p.S1828_P1834del | In Frame Del (DEL) | VAF 34/116 reads (29%) | catalogued as rs770798456; called by mutect2, varscan2
- POLR2I | c.263+5G>A | Splice Region (SNP) | VAF 23/98 reads (23%) | catalogued as rs201433073; called by muse, mutect2, varscan2
- POU4F1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV65884889; called by muse, mutect2
- PRKCG | c.1676A>T p.D559V | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54731123; called by mutect2, varscan2
- PTPRJ | c.3719+1G>T p.X1240_splice | Splice Site (SNP) | VAF 53/99 reads (54%) | catalogued as COSV69253789; called by muse, mutect2, varscan2
- RASGRP4 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53097089; called by muse, mutect2
- RFPL3 | c.429C>A p.D143E (on ENST00000249007 / NM_001098535.1; = p.D114E on NM_006604.2) | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780270312, COSV50751638; called by muse, mutect2, varscan2
- RGPD4 | c.5197C>A p.L1733I | Missense Mutation (SNP) | VAF 167/829 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as rs570292087, COSV61747969; called by muse, mutect2, varscan2
- ROBO2 | c.3179A>C p.K1060T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV59930237; called by muse, mutect2, varscan2
- RPP25L | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.636); catalogued as COSV52408482, COSV52408503; called by muse, mutect2, varscan2
- RTL1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs769924231, COSV66017274; called by muse, mutect2, varscan2
- SDHA | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.322); catalogued as rs369321221, COSV53771891; called by muse, mutect2, varscan2
- SDK1 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs753638529, COSV67360716; called by muse, mutect2, varscan2
- SEMA3C | c.548T>A p.L183H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54852969; called by muse, mutect2, varscan2
- SF1 | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV57116574; called by muse, mutect2, varscan2
- SIX4 | c.1193C>G p.S398* | Nonsense Mutation (SNP) | VAF 29/158 reads (18%) | catalogued as COSV53670984; called by muse, mutect2, varscan2
- SLC26A9 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1358483614, COSV61600895, COSV61604622; called by muse, mutect2, varscan2
- SLITRK1 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV65676968; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 32/438 reads (7%) | PolyPhen possibly damaging (0.77); catalogued as COSV50078069; called by muse, mutect2
- SUPT16H | c.2880_2882del p.E960del | In Frame Del (DEL) | VAF 32/210 reads (15%) | catalogued as rs773988222; called by pindel, varscan2
- TENM4 | c.6772G>A p.D2258N | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53655655, COSV53666603; called by muse, mutect2
- TFDP1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as COSV64741863; called by muse, mutect2, varscan2
- TGIF2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV65836242, COSV65836754; called by muse, mutect2, varscan2
- TIAM2 | c.2836G>T p.G946W | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59700406; called by muse, mutect2, varscan2
- TMEM132D | c.2366G>A p.G789E | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67160422, COSV67161719; called by muse, mutect2
- TNS3 | c.2620A>T p.S874C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV60796140; called by muse, mutect2, varscan2
- TRPA1 | c.1385G>T p.C462F | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs944401339, COSV51570057; called by muse, mutect2, varscan2
- TRPV5 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377425606; called by muse, mutect2, varscan2
- UGT1A4 | c.692A>G p.Y231C | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59395218; called by muse, mutect2, varscan2
- USP7 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as COSV61216569; called by muse, mutect2, varscan2
- ZNF469 | c.4438T>C p.S1480P (on ENST00000437464; = p.S1508P on NM_001367624.2) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV71259218; called by muse, mutect2, varscan2
- ZNF490 | c.748T>A p.Y250N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV61008781; called by muse, mutect2, varscan2
- ZNF584 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV59723082; called by muse, mutect2
- ZNF705A | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63733583; called by muse, mutect2
- ZNF721 | c.113G>T p.R38M (on ENST00000338977; = p.R50M on NM_133474.4) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV59095569; called by muse, mutect2, varscan2
- ZNF776 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs755162710, COSV57816116; called by muse, mutect2, varscan2
- ZNF776 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV57816128; called by muse, mutect2
- ALB | c.662_663del p.R221Tfs*30 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | called by pindel, varscan2
- CAPN6 | c.281del p.E94Gfs*42 | Frame Shift Del (DEL) | VAF 62/95 reads (65%) | called by mutect2, pindel, varscan2
- CCDC74B | c.1007+6_1007+19del | Splice Region (DEL) | VAF 48/145 reads (33%) | called by mutect2, varscan2
- OR5T1 | c.910_938del p.L304Qfs*12 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | called by mutect2, pindel
- SCN9A | c.4783_4784del p.L1595Sfs*2 (on ENST00000303354; = p.L1584Sfs*2 on NM_002977.3) | Frame Shift Del (DEL) | VAF 42/122 reads (34%) | called by mutect2, pindel, varscan2
- SLC1A1 | c.1275_1290del p.V426Rfs*5 | Frame Shift Del (DEL) | VAF 34/204 reads (17%) | called by mutect2, pindel*, varscan2*
- SLC30A10 | c.1182_1187del p.D395_L396del | In Frame Del (DEL) | VAF 28/242 reads (12%) | called by mutect2, pindel
- TANC2 | c.767A>T p.Q256L | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.248); called by muse, mutect2
- TEX55 | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2
- ADI1 | c.525G>A p.L175= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as COSV59377608; called by muse, varscan2
- ATP1A4 | c.33T>G p.A11= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV63627887; called by muse, mutect2, varscan2
- CAMTA1 | c.2085G>T p.S695= | Silent (SNP) | VAF 74/105 reads (70%) | catalogued as COSV57881146, COSV57918933; called by muse, mutect2, varscan2
- CYLC1 | c.633T>A p.T211= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV61414562; called by muse, mutect2, varscan2
- DNAJB1 | c.60C>T p.I20= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV54317688; called by muse, mutect2, varscan2
- DOCK5 | c.4587C>T p.I1529= | Silent (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- EBF1 | c.1521C>T p.N507= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs763968946, COSV58184625; called by muse, mutect2, varscan2
- EFCAB3 | c.1095C>T p.D365= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as COSV59503833; called by muse, mutect2, varscan2
- FSCB | c.873C>A p.V291= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV61219155; called by muse, mutect2, varscan2
- GDF2 | c.912G>A p.T304= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs201627211; called by mutect2, varscan2
- GPR179 | c.3522C>T p.S1174= (on ENST00000621958; = p.S1173= on NM_001004334.4) | Silent (SNP) | VAF 41/172 reads (24%) | catalogued as rs769135444; called by muse, mutect2, varscan2
- HORMAD1 | c.411C>T p.N137= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as rs368484414; called by muse, mutect2, varscan2
- HSPA12B | c.741G>A p.S247= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs775745835, COSV54768545; called by muse, mutect2, varscan2
- IKZF3 | c.1275C>T p.Y425= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs765182589, COSV53101138, COSV53102997; called by muse, mutect2, varscan2
- ITGAD | c.918G>A p.A306= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as rs141660381; called by muse, mutect2, varscan2
- LSM14A | c.291A>G p.S97= | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as rs1404420063, COSV70884720; called by muse, mutect2, varscan2
- MAG | c.1314G>C p.P438= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV62702204; called by muse, mutect2, varscan2
- NBEAL1 | c.7359A>T p.G2453= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as COSV68916805; called by muse, mutect2
- NBPF9 | c.1149G>A p.K383= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as COSV99914378; called by muse, mutect2
- PIAS3 | c.1797T>G p.P599= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs782645439, COSV57908136; called by muse, mutect2, varscan2
- PIP4K2C | c.154C>T p.L52= | Silent (SNP) | VAF 83/180 reads (46%) | catalogued as rs1385841726, COSV61606721; called by muse, mutect2, varscan2
- PIWIL2 | c.93T>G p.A31= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as COSV63253285; called by muse, mutect2, varscan2
- RET | c.2706G>A p.E902= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV60703614; called by muse, mutect2, varscan2
- TARBP1 | c.4068A>T p.L1356= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as COSV50197715; called by muse, mutect2, varscan2
- TMEM181 | c.873C>T p.F291= | Silent (SNP) | VAF 130/292 reads (45%) | catalogued as COSV65565198; called by muse, mutect2, varscan2
- UBE2U | c.735C>T p.H245= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs774169762; called by muse, mutect2, varscan2
- UFD1 | c.60C>G p.S20= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV54247567; called by muse, mutect2, varscan2
- ZNF335 | c.1947C>T p.F649= | Silent (SNP) | VAF 10/179 reads (6%) | catalogued as COSV59819385; called by muse, mutect2
- HLA-G | c.*17C>T | 3'UTR (SNP) | VAF 54/196 reads (28%) | catalogued as COSV100826998; called by muse, mutect2
- LINC01553 | n.396C>A | RNA (SNP) | VAF 70/313 reads (22%) | called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516139 A>C | 5'Flank (SNP) | VAF 79/173 reads (46%) | catalogued as COSV53064700; called by muse, mutect2, varscan2
- OSGIN1 | n.1875G>A | RNA (SNP) | VAF 46/204 reads (23%) | catalogued as COSV59422493; called by muse, mutect2, varscan2
- TSEN34 | c.-113C>T | 5'UTR (SNP) | VAF 25/124 reads (20%) | catalogued as COSV99824968; called by muse, mutect2, varscan2
- ZNF429 | c.-47T>C | 5'UTR (SNP) | VAF 17/55 reads (31%) | catalogued as rs1423626976, COSV100642018; called by muse, mutect2, varscan2
